Gene-level copy-number profile of specimen HCM-BROD-0045-C16-85A from HCMI case HCM-BROD-0045-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.1 years (21,217 days).
Specimen HCM-BROD-0045-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8cc336ce-60a0-4770-a868-d507da854637.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0045-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/c722c889-2861-483e-8f05-498e1821c6dd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 672; copy number 2: 6,800; copy number 3: 29,319; copy number 4: 16,904; copy number 5: 2,644; copy number 6: 1,820; copy number 7: 28; copy number 8: 145; copy number 9: 55; copy number 10: 27; copy number 11: 214; copy number 12: 10; copy number 13: 5; copy number 15: 135; copy number 16: 7; copy number 17: 1; copy number 20: 41; copy number 30: 2; copy number 32: 6; copy number 34: 1; copy number 36: 29.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr21:8,762,386–8,880,976, 4 genes: CR381670.2, SNX18P10, MTCO1P1, CR381670.1.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 706 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 7: AC239859.2, LINC02799.
- chr5:70,415,352–70,448,015, 1 gene, copy number 17: GTF2H2B.
- chr7:54,752,250–56,687,366, 72 genes, copy number 11–34 (broad region; genes not listed).
- chr7:57,599,794–57,837,046, 22 genes, copy number 7: NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:112,422,887–112,490,941, 4 genes, copy number 7 (within-gene range 3–7): IFRD1, AC079741.1, AC005192.1, AC079741.2.
- chr7:114,922,359–117,323,152, 52 genes, copy number 10–36: MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr8:11,486,894–12,115,516, 25 genes, copy number 9–10: BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr11:65,570,460–72,005,715, 274 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr11:82,729,940–83,423,516, 29 genes, copy number 9: FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:98,130,239–109,263,564, 140 genes, copy number 8–15 (broad region; genes not listed).
- chr11:117,204,337–117,232,525, 1 gene, copy number 8 (within-gene range 6–8): PCSK7.
- chr11:117,232,625–119,067,698, 82 genes, copy number 8–15 (within-gene range 1–15) (broad region; genes not listed).
- chr22:15,784,959–15,829,984, 2 genes, copy number 9 (within-gene range 4–9): DUXAP8, AP000526.1.

Autosomal genes at a single copy (total copy number 1): 433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
